Somatic mutation profile of tumor specimen MP2PRT-PAPAYV-TMP1-A (aliquot MP2PRT-PAPAYV-TMP1-A-1-0-D-A83L-36) from MP2PRT case MP2PRT-PAPAYV, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.7 years (2,448 days).
Specimen MP2PRT-PAPAYV-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d4bd0fbe-fc3c-4484-a68b-eb17f105509f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPAYV-NM1-A (Blood Derived Cancer - Bone Marrow, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPAYV-NM1-A-1-0-D-A83L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a021ff99-9a72-431f-b82f-e7eb6c6a4d02

The open-access MAF lists 50 somatic variants for this specimen: 37 protein-altering or splice-affecting, 12 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 12, Nonsense Mutation 3, Splice Region 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GJB1 | c.622G>A p.E208K | Missense Mutation (SNP) | VAF 129/765 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1555937270, CD1411810, CM940837; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- PTPN11 | c.215C>T p.A72V | Missense Mutation (SNP) | VAF 64/369 reads (17%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.806); catalogued as rs121918454, CM013417, COSV61005613, COSV61008344, COSV61012146; ClinVar: likely pathogenic / conflicting interpretations of pathogenicity; called by muse, varscan2
- ABCA13 | c.12925C>T p.R4309C | Missense Mutation (SNP) | VAF 60/304 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.398); catalogued as rs763439416, COSV68949713; called by muse, mutect2, varscan2
- ACP4 | c.193C>T p.R65* | Nonsense Mutation (SNP) | VAF 59/324 reads (18%) | catalogued as rs993542537; called by muse, mutect2, varscan2
- ACTBL2 | c.86G>A p.R29Q | Missense Mutation (SNP) | VAF 61/471 reads (13%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.176); catalogued as rs768491915, COSV70661310; called by mutect2, varscan2
- ANKRD30B | c.2560G>A p.D854N | Missense Mutation (SNP) | VAF 28/242 reads (12%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.197); catalogued as COSV57703722; called by muse, mutect2, varscan2
- BNC1 | c.199G>A p.A67T | Missense Mutation (SNP) | VAF 50/267 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100597116, COSV61757588; called by muse, mutect2, varscan2
- CASKIN2 | c.2446G>A p.E816K | Missense Mutation (SNP) | VAF 75/741 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs547029082; called by muse, mutect2, varscan2
- CLCA1 | c.1114G>A p.A372T | Missense Mutation (SNP) | VAF 65/349 reads (19%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as rs778793374, COSV52328159; called by muse, mutect2, varscan2
- FAM83H | c.2380C>T p.R794C | Missense Mutation (SNP) | VAF 150/829 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.68); catalogued as rs1554622297, COSV62029348; called by muse, mutect2, varscan2
- GALC | c.1331C>G p.S444C | Missense Mutation (SNP) | VAF 8/194 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.669); catalogued as COSV54323162; called by muse, mutect2
- GCM1 | c.797G>A p.R266H | Missense Mutation (SNP) | VAF 73/455 reads (16%) | SIFT tolerated (0.53); PolyPhen benign (0.125); catalogued as rs367761617; called by muse, mutect2, varscan2
- INSYN2B | c.718C>T p.R240C | Missense Mutation (SNP) | VAF 79/443 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs761122238; called by muse, mutect2, varscan2
- KLHL34 | c.1663C>T p.R555W | Missense Mutation (SNP) | VAF 127/777 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as rs914654948, COSV101070016; called by muse, mutect2, varscan2
- MYH6 | c.4306C>T p.R1436C | Missense Mutation (SNP) | VAF 86/622 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs746893658; called by muse, mutect2, varscan2
- NCKAP5L | c.1384C>T p.P462S | Missense Mutation (SNP) | VAF 79/422 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.858); catalogued as rs1197742825; called by muse, mutect2, varscan2
- NSD2 | c.3295G>A p.E1099K | Missense Mutation (SNP) | VAF 36/528 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs772470710, COSV56386422; ClinVar: uncertain significance; called by muse, mutect2
- OR6C74 | c.688C>T p.Q230* | Nonsense Mutation (SNP) | VAF 55/247 reads (22%) | catalogued as COSV59606057; called by muse, mutect2, varscan2
- PCDHA12 | c.2159C>T p.A720V | Missense Mutation (SNP) | VAF 82/435 reads (19%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.021); catalogued as COSV56497066; called by muse, mutect2, varscan2
- PROS1 | c.955G>C p.E319Q | Missense Mutation (SNP) | VAF 12/188 reads (6%) | SIFT tolerated (0.91); PolyPhen benign (0.193); catalogued as CM163616, COSV101260858, COSV67775570; called by muse, mutect2
- SLIT3 | c.4484G>A p.R1495Q | Missense Mutation (SNP) | VAF 75/535 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs758664561; called by muse, mutect2, varscan2
- STRA6 | c.1901G>A p.R634H | Missense Mutation (SNP) | VAF 28/572 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as rs201627246, COSV51434322; called by muse, mutect2
- ARL6IP4 | c.1023C>T p.V341= (on ENST00000315580 / NM_018694.3; = p.V322= on NM_016638.3 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 40/296 reads (14%) | called by muse, mutect2, varscan2
- CDH6 | c.659C>T p.A220V | Missense Mutation (SNP) | VAF 45/294 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.603); called by muse, mutect2, varscan2
- FRMPD4 | c.2415G>A p.M805I | Missense Mutation (SNP) | VAF 79/540 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.297); called by muse, mutect2, varscan2
- HOOK3 | c.1870C>T p.Q624* | Nonsense Mutation (SNP) | VAF 41/250 reads (16%) | called by muse, mutect2, varscan2
- HOXD13 | c.74C>G p.S25C | Missense Mutation (SNP) | VAF 20/774 reads (3%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.02); called by muse, mutect2
- HUWE1 | c.6229G>A p.E2077K | Missense Mutation (SNP) | VAF 98/593 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- KL | c.577C>T p.H193Y | Missense Mutation (SNP) | VAF 22/638 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KMT2C | c.2769G>T p.G923= | Splice Region (SNP) | VAF 48/225 reads (21%) | called by muse, varscan2
- NCAM2 | c.1302G>C p.W434C | Missense Mutation (SNP) | VAF 38/368 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PPARGC1A | c.1549G>A p.E517K | Missense Mutation (SNP) | VAF 85/455 reads (19%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- RNFT2 | c.710C>G p.S237C | Missense Mutation (SNP) | VAF 11/270 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- TASOR | c.2545G>A p.D849N (on ENST00000355628 / NM_001365636.2; = p.D453N on NM_015224.3) | Missense Mutation (SNP) | VAF 71/348 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- TTN | c.19246G>A p.E6416K (on ENST00000591111; = p.E5489K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/434 reads (3%) | PolyPhen benign (0.423); called by muse, mutect2
- UBA2 | c.1058A>T p.D353V | Missense Mutation (SNP) | VAF 42/237 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- XRCC5 | c.1675G>A p.E559K | Missense Mutation (SNP) | VAF 15/278 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.265); called by muse, mutect2
- ACAT1 | c.6T>G p.A2= | Silent (SNP) | VAF 16/454 reads (4%) | called by muse, mutect2
- BRPF3 | c.3450G>A p.R1150= | Silent (SNP) | VAF 48/280 reads (17%) | catalogued as rs1050105043; called by mutect2, varscan2
- COX6A2 | c.261G>A p.V87= | Silent (SNP) | VAF 15/539 reads (3%) | called by muse, mutect2
- FILIP1 | c.1005G>A p.L335= | Silent (SNP) | VAF 75/435 reads (17%) | called by muse, mutect2, varscan2
- ICMT | c.174C>T p.L58= | Silent (SNP) | VAF 92/444 reads (21%) | catalogued as rs1232382511; called by mutect2, varscan2
- IGKV2D-30 | c.189G>A p.Q63= | Silent (SNP) | VAF 31/419 reads (7%) | catalogued as rs1397865763; called by muse, mutect2
- KCNH3 | c.1509C>T p.I503= | Silent (SNP) | VAF 21/474 reads (4%) | called by muse, mutect2
- NLRP4 | c.519G>A p.S173= | Silent (SNP) | VAF 72/360 reads (20%) | catalogued as rs749484722, COSV56709907; called by muse, varscan2
- NLRP8 | c.834C>T p.P278= | Silent (SNP) | VAF 89/427 reads (21%) | catalogued as rs762189376, COSV52584959; called by muse, mutect2, varscan2
- PKHD1L1 | c.351C>T p.D117= | Silent (SNP) | VAF 51/331 reads (15%) | catalogued as rs745725110, COSV65736734; called by muse, mutect2, varscan2
- SLC7A3 | c.1554G>T p.L518= | Silent (SNP) | VAF 57/420 reads (14%) | called by muse, mutect2, varscan2
- ZMAT1 | c.1728C>T p.I576= | Silent (SNP) | VAF 77/541 reads (14%) | called by muse, mutect2, varscan2
- STXBP6 | c.452-117G>A | Intron (SNP) | VAF 73/451 reads (16%) | catalogued as rs774170823; called by muse, mutect2, varscan2
